Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A65J, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A65J-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, LYMPHADENECTOMY –
EIGHT LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA (0/8).

PART 2: LYMPH NODES, LEFT PELVIC, LYMPHADENECTOMY –
THREE LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA SEEN (0/3).

PART 3: PROSTATE, RADICAL PROSTATECTOMY –
A. INVASIVE POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE 4 + 5 = 9 (see comment).
B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND THE LEFT LOBES OF THE PROSTATE AND CONSTITUTES APPROXIMATELY 10% OF THE TISSUE EVALUATED.
C. THE TUMOR MEASURES 2.0 CM IN GREATEST NODULAR DIMENSION.
D. ESTABLISHED EXTRACAPSULAR EXTENSION IS IDENTIFIED. THE EXTRACAPSULAR EXTENSION IS SEEN IN THE REGIONS OF THE RIGHT POSTERIOR APEX (SLIDE 3U), THE RIGHT POSTERIOR MID (SLIDE 3Z), AND THE RIGHT POSTERIOR BASE (SLIDE 3W).
E. ALL INKED MARGINS OF RESECTION ARE FREE OF CARCINOMA.
F. BILATERAL SEMINAL VESICLES, NO EVIDENCE OF CARCINOMA SEEN.
G. MULTIFOCAL PERINEURAL INVASION BY THE CARCINOMA IS SEEN.
H. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS SEEN.
I. TNM STAGE: T3a N0 MX.
J. HISTOLOGIC GRADE: G3-4 (POORLY DIFFERENTIATED/UNDIFFERENTIATED).

PART 4: URETHRA, URETHRAL MARGIN, BIOPSY –
BENIGN URETHRAL TISSUE, NO EVIDENCE OF CARCINOMA SEEN.

PART 5: SOFT TISSUE, DENONVILLIERS, BIOPSY –
A. SOFT TISSUE WITH SEMINAL VESICLE-TYPE TISSUE.
B. NO EVIDENCE OF CARCINOMA SEEN.

COMMENT:

The prostatic adenocarcinoma shows Gleason patterns 3, 4 and 5. Gleason pattern 5 constitutes approximately 10% of the tissues evaluated. Gleason pattern 3 constitutes approximately 35% of the tissue evaluated and Gleason pattern 4 constitutes approximately 55% of the tissue evaluated.

Based on the distribution of the Gleason pattern, this carcinoma is best scored as a Gleason score of 4 + 5 = 9.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 35
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	5
GLEASON SUM SCORE:	9
GLEASON 4/5 PERCENTAGE:	65%
WEIGHT OF PROSTATE:	50.5gm
TUMOR SIZE:	Maximum dimension: 2.0 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	11
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

CHF ICD-O-3
Adenocarcinoma, acinar
path
Adenocarcinoma NOS
8140/3
Site: Prostate NOS
C61.9
QW516/13

**PATIENT HISTORY:**

Preop Diagnosis: PROSTATE CANCER
Postop Diagnosis: PROSTATE CANCER
Surgical Procedure: PROSTATECTOMY RADICAL
Surgical Procedure: LYMPHADENECTOMY PELVIC
Surgical Procedure: CYSTOSCOPY
Reason previous hospitalization/surgery = umbilical hernia repair.
Date of Surgery/Hospitalization =
Reason previous hospitalization/surgery = Moh's surgery scalp secondary to skin cancer.
Date of Surgery/Hospitalization =
Cardiovascular medical history = Current: denies history of hypertension; states was never on meds for hypertension.
Musculoskeletal medical history = Other: some knee pain, sees chiropractor on occasion.
Gastrointestinal medical history = Other: appetite good; had recent weight loss due to diet and exercise; bowels regular; denies reflux.
Eye/ear medical history = Other: wears glasses & contacts, vision good with use of.
Genitourinary/renal medical history = Other: prostate cancer elevated PSA 01/12, biopsy x2; nocturia 2-3 times night with urinary frequency during day with occasional dribbling.
Skin condition medical history = Other: small scattered abrasions anterior lower legs "bumped into table".
Oncology medical history = Prostate cancer, Skin cancer, Other: squamous cell skin cancer.

The patient is a -year-old white male with a history of PSA value of 35. The patient also has a history of biopsy on this biopsy reveals: poorly differentiated prostatic adenocarcinoma Gleason score 4+5=9 in the right lobe.

Source: NCI Genomic Data Commons file 89b060a2-824e-491d-a07e-4cef9d915605 (TCGA-EJ-A65J.DBB16691-F1A8-40B8-99E7-FB206B3B680C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).